Somatic mutation profile of tumor specimen C3N-03840-01 (aliquot CPT0236780008) from CPTAC case C3N-03840, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 59.5 years (21,749 days).
Specimen C3N-03840-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78ce9a13-3207-4087-a933-9885d962e041.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03840-31 (Blood Derived Normal), aliquot CPT0236840002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56b079de-26e0-4392-8bc2-d3d5799effd6

The open-access MAF lists 45 somatic variants for this specimen: 30 protein-altering or splice-affecting, 11 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 11, Splice Region 3, Nonsense Mutation 1, 5'UTR 1, 5'Flank 1, Intron 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.3826C>T p.R1276* | Nonsense Mutation (SNP) | VAF 17/217 reads (8%) | hotspot (GDC flag); catalogued as COSV61370466; called by muse, mutect2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 61/470 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATM | c.8762C>G p.T2921R | Missense Mutation (SNP) | VAF 70/669 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV53726751; called by muse, mutect2, varscan2
- CACNA1E | c.2119G>A p.A707T | Missense Mutation (SNP) | VAF 50/552 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1273665569; called by muse, mutect2
- CLTC | c.4981G>A p.A1661T | Missense Mutation (SNP) | VAF 16/301 reads (5%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.835); catalogued as rs1271278136, COSV52244627; called by muse, mutect2
- DENND4B | c.4460G>A p.R1487Q | Missense Mutation (SNP) | VAF 65/365 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs759874404, COSV100768658, COSV63411501; called by muse, mutect2, varscan2
- FUBP1 | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 40/350 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV53934420, COSV53935551; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1711C>A p.Q571K | Missense Mutation (SNP) | VAF 38/480 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.08); catalogued as rs756892831, COSV100148575; called by muse, mutect2
- KIR3DL3 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 90/466 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs544733307, COSV52546043; called by muse, mutect2, varscan2
- MARCHF11 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 37/335 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs921889840, COSV100198278, COSV60126013, COSV60127080; called by muse, mutect2, varscan2
- MED12L | c.5975C>T p.P1992L | Missense Mutation (SNP) | VAF 98/672 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs766967153, COSV56379954; called by muse, mutect2, varscan2
- MYH13 | c.3536G>A p.R1179H | Missense Mutation (SNP) | VAF 90/1014 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs369467746; called by muse, mutect2
- PLCH2 | c.2959+7C>T | Splice Region (SNP) | VAF 72/672 reads (11%) | catalogued as rs551787907, COSV53939907; called by muse, mutect2, varscan2
- POLR1D | c.24G>A p.E8= | Splice Region (SNP) | VAF 56/614 reads (9%) | catalogued as rs1190644767; called by muse, mutect2
- SLC28A1 | c.1601C>T p.T534M | Missense Mutation (SNP) | VAF 74/812 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs145160651; called by muse, mutect2
- SVEP1 | c.8929C>T p.P2977S | Missense Mutation (SNP) | VAF 44/432 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV52842592; called by muse, mutect2, varscan2
- TADA2A | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs748285471; called by muse, mutect2
- TGFBR2 | c.1258G>C p.G420R | Missense Mutation (SNP) | VAF 66/496 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55453316; called by muse, mutect2, varscan2
- ZXDA | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 46/726 reads (6%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.65); catalogued as rs1216633923; called by muse, mutect2
- ACTN4 | c.2666C>T p.P889L | Missense Mutation (SNP) | VAF 81/822 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2
- ALK | c.200A>G p.Y67C | Missense Mutation (SNP) | VAF 44/484 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- CDHR5 | c.614T>C p.V205A | Missense Mutation (SNP) | VAF 31/284 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.031); called by muse, mutect2
- CHD3 | c.5591-3C>T | Splice Region (SNP) | VAF 96/963 reads (10%) | called by muse, mutect2
- CHST13 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- CRHR2 | c.1060T>C p.F354L | Missense Mutation (SNP) | VAF 34/407 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.631); called by muse, mutect2
- DAB2IP | c.2426C>T p.T809I (on ENST00000408936; = p.T781I on NM_032552.3) | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- EP300 | c.265A>G p.S89G | Missense Mutation (SNP) | VAF 62/662 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2
- LRFN1 | c.1913T>C p.V638A | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCOA6 | c.2774dup p.N925Kfs*2 | Frame Shift Ins (INS) | VAF 14/120 reads (12%) | called by mutect2, pindel, varscan2
- PLCL1 | c.1175A>C p.E392A | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.14); called by muse, mutect2
- ATP9B | c.1395A>G p.L465= | Silent (SNP) | VAF 28/204 reads (14%) | called by muse, mutect2, varscan2
- BASP1 | c.570G>A p.T190= | Silent (SNP) | VAF 40/350 reads (11%) | catalogued as rs759514967; called by muse, mutect2, varscan2
- C16orf96 | c.312T>A p.T104= | Silent (SNP) | VAF 25/628 reads (4%) | called by muse, mutect2
- DNAH7 | c.6156G>A p.E2052= | Silent (SNP) | VAF 25/195 reads (13%) | catalogued as rs370194780; called by muse, mutect2, varscan2
- EPPK1 | c.2217C>T p.P739= | Silent (SNP) | VAF 64/600 reads (11%) | catalogued as rs1345005551; called by muse, mutect2
- FAT1 | c.11214C>T p.C3738= | Silent (SNP) | VAF 74/788 reads (9%) | catalogued as rs562587924; called by muse, mutect2
- HYDIN | c.7470G>A p.A2490= | Silent (SNP) | VAF 38/426 reads (9%) | catalogued as rs1798530; called by muse, mutect2
- NCKAP5L | c.1395G>A p.S465= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs548007920; called by muse, mutect2
- NCOA6 | c.2577A>C p.G859= | Silent (SNP) | VAF 32/235 reads (14%) | catalogued as rs1247593011; called by muse, mutect2, varscan2
- SEC14L5 | c.1701C>T p.T567= | Silent (SNP) | VAF 24/238 reads (10%) | called by muse, mutect2, varscan2
- TOPBP1 | c.4377G>A p.Q1459= | Silent (SNP) | VAF 33/304 reads (11%) | catalogued as COSV99604876; called by muse, mutect2
- ATP2B2 | chr3:10449584 C>T | 5'Flank (SNP) | VAF 79/594 reads (13%) | catalogued as rs773641502; called by muse, mutect2, varscan2
- DHRS9 | c.-354A>T | 5'UTR (SNP) | VAF 34/346 reads (10%) | called by muse, mutect2
- NTF4 | c.*1G>A | 3'UTR (SNP) | VAF 54/601 reads (9%) | called by muse, mutect2
- SASH1 | c.386+13C>T | Intron (SNP) | VAF 36/297 reads (12%) | called by muse, mutect2, varscan2
